Somatic mutation profile of tumor specimen MMRF_1888_1_BM_CD138pos (aliquot MMRF_1888_1_BM_CD138pos_T1_KHS5U_L08086) from MMRF case MMRF_1888, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.8 years (23,685 days).
Specimen MMRF_1888_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72c73b00-853f-4a7f-95a0-d24c4f3d107e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1888_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1888_1_PB_Whole_C2_KHS5U_L08087; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f743602-0926-4d02-807c-54da9935fb93

The open-access MAF lists 124 somatic variants for this specimen: 55 protein-altering or splice-affecting, 14 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 38, Silent 14, Intron 9, Splice Site 3, 5'UTR 3, 5'Flank 3, Splice Region 3, Nonsense Mutation 2, Frame Shift Del 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP1 | c.1180+6G>A | Splice Region (SNP) | VAF 13/24 reads (54%) | catalogued as rs535579955; called by muse, mutect2, varscan2
- CEACAM5 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 66/291 reads (23%) | catalogued as rs939162828, COSV55751135; called by muse, mutect2, varscan2
- CSNK1A1L | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs201851808, COSV65789708; called by muse, mutect2, varscan2
- GRIN1 | c.2243C>T p.T748M | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59297373; called by muse, mutect2, varscan2
- H4C6 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs778148505, COSV66685691; called by muse, mutect2, varscan2
- HYAL3 | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1553710994; called by muse, mutect2
- IGHV2-70D | c.166A>G p.S56G | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1240632108; called by muse, varscan2
- IGLV4-60 | c.136A>G p.S46G | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs1555880889; called by muse, varscan2
- IGLV4-60 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs78099525; called by muse, varscan2
- IGLV4-60 | c.170A>G p.H57R | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs771488698; called by muse, varscan2
- IGLV4-60 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as rs567826954; called by muse, varscan2
- IGLV5-45 | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 74/74 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs369863120; called by muse, mutect2, varscan2
- IGLV5-45 | c.354G>T p.W118C | Missense Mutation (SNP) | VAF 82/87 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs544739530; called by muse, mutect2, varscan2
- IGLV7-46 | c.140C>G p.A47G | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT tolerated (0.39); PolyPhen benign (0.263); catalogued as rs188705617; called by muse, mutect2, varscan2
- IRF1 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.81); PolyPhen benign (0.15); catalogued as COSV55377088; called by muse, mutect2, varscan2
- ITCH | c.1970C>T p.T657M (on ENST00000262650 / NM_001257137.3; = p.T616M on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445655265, COSV52933847; called by muse, mutect2, varscan2
- KLHL18 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1218263060, COSV51744247; called by muse, mutect2, varscan2
- LRRIQ4 | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.247); catalogued as COSV99246684; called by muse, mutect2, varscan2
- NRIP1 | c.876A>C p.Q292H | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100012485; called by muse, mutect2, varscan2
- PDILT | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs765339152, COSV56701392; called by muse, mutect2, varscan2
- PLCD3 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs200400202; called by muse, mutect2, varscan2
- PROSER2 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271037323; called by muse, mutect2, varscan2
- RERE | c.3545G>A p.R1182Q | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.788); catalogued as rs750425197; called by muse, mutect2, varscan2
- SLC26A7 | c.1897T>A p.S633T | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.982); catalogued as rs1230190701; called by muse, mutect2, varscan2
- STEAP3 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs140512748; called by muse, mutect2, varscan2
- UBA1 | c.2980G>A p.V994M | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs781984124; called by muse, mutect2, varscan2
- AGBL4 | c.1144A>G p.T382A | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ARHGAP12 | c.2011A>G p.K671E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAD | c.5904G>A p.M1968I | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CNPY3 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- E2F8 | c.1489G>T p.V497F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- HERPUD1 | c.432-7T>C | Splice Region (SNP) | VAF 26/43 reads (60%) | called by muse, mutect2, varscan2
- HNF1B | c.835T>C p.S279P | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2
- IGHV1-69D | c.299T>A p.M100K | Missense Mutation (SNP) | VAF 69/74 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- IGHV3-30 | c.310A>G p.S104G | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, varscan2
- IGLV1-44 | c.206_217delinsTTACTACTGATG p.Y69_Q73delinsFTTDE | Missense Mutation (ONP) | VAF 10/28 reads (36%) | called by pindel, varscan2*
- IGLV4-60 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- IGLV5-52 | c.335A>C p.D112A | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.308); called by muse, mutect2
- KTN1 | c.2367G>A p.Q789= | Splice Region (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- MON2 | c.4011_4013del p.A1338del | In Frame Del (DEL) | VAF 39/87 reads (45%) | called by mutect2, pindel, varscan2
- MS4A15 | c.-28-2A>G | Splice Site (SNP) | VAF 109/228 reads (48%) | called by muse, mutect2, varscan2
- MYO1E | c.588dup p.S197Ifs*2 | Frame Shift Ins (INS) | VAF 56/230 reads (24%) | called by mutect2, pindel, varscan2
- NDUFC1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 97/179 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OTOGL | c.3735C>G p.S1245R (on ENST00000547103; = p.S1236R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- P4HTM | c.277C>G p.P93A | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PZP | c.2395T>C p.F799L | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF17 | c.3701C>T p.A1234V | Missense Mutation (SNP) | VAF 81/149 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- RPL5 | c.175_176del p.D59Yfs*53 | Frame Shift Del (DEL) | VAF 49/138 reads (36%) | called by pindel, varscan2
- SCARF2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); called by muse, mutect2
- SLC25A27 | c.806T>C p.L269S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SNX4 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 99/207 reads (48%) | called by muse, mutect2, varscan2
- TEF | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIM41 | c.1163+5_1163+6del p.X388_splice | Splice Site (DEL) | VAF 42/115 reads (37%) | called by pindel, varscan2
- TTLL4 | c.1268T>C p.L423P | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- UXS1 | c.906_908+2del p.X302_splice | Splice Site (DEL) | VAF 55/142 reads (39%) | called by mutect2, pindel, varscan2
- ABCA10 | c.1371A>G p.Q457= | Silent (SNP) | VAF 42/58 reads (72%) | catalogued as rs370083970; called by muse, mutect2, varscan2
- ARAF | c.516G>A p.S172= | Silent (SNP) | VAF 77/179 reads (43%) | catalogued as rs56202823, COSV51694528; called by muse, mutect2, varscan2
- ATP9A | c.732C>T p.S244= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs557141465, COSV58763943; called by muse, mutect2, varscan2
- CACNA1A | c.4422C>T p.D1474= | Silent (SNP) | VAF 76/205 reads (37%) | catalogued as rs374555263; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAMK2A | c.582G>A p.V194= | Silent (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- COL4A5 | c.4908T>G p.G1636= | Silent (SNP) | VAF 24/44 reads (55%) | called by muse, varscan2
- FGF23 | c.174T>C p.N58= | Silent (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- FLG | c.945G>A p.G315= | Silent (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- FSIP2 | c.660C>T p.R220= | Silent (SNP) | VAF 29/337 reads (9%) | called by muse, mutect2
- IGLV1-44 | c.327A>T p.A109= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as rs746483918; called by muse, mutect2
- IGLV7-46 | c.264T>C p.L88= | Silent (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- SHISA7 | c.1425C>T p.H475= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV66244654; called by muse, mutect2, varscan2
- TMTC2 | c.2340T>A p.A780= | Silent (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2
- WFS1 | c.342C>T p.A114= | Silent (SNP) | VAF 44/128 reads (34%) | catalogued as rs201151892; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- AC004837.1 | chr7:39609679 C>T | 5'Flank (SNP) | VAF 22/84 reads (26%) | catalogued as rs753943185, COSV101352385; called by muse, mutect2
- ARL4C | c.*2589C>G | 3'UTR (SNP) | VAF 50/110 reads (45%) | catalogued as rs1344331977; called by muse, mutect2, varscan2
- ATP5MC2 | chr12:53676644 A>G | 5'Flank (SNP) | VAF 55/77 reads (71%) | called by muse, mutect2, varscan2
- BCAT1 | c.7-469G>A | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- CCHCR1 | c.*61G>A | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.*174C>G | 3'UTR (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- CHN1 | c.550-104G>A | Intron (SNP) | VAF 98/248 reads (40%) | catalogued as COSV55035641; called by muse, mutect2, varscan2
- CIBAR1 | c.261+866A>T | Intron (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- CMPK2 | c.*1263G>T | 3'UTR (SNP) | VAF 34/61 reads (56%) | called by muse, mutect2, varscan2
- COX11 | c.*1680G>A | 3'UTR (SNP) | VAF 14/21 reads (67%) | called by muse, mutect2, varscan2
- DOCK9 | chr13:98978047 G>A | 5'Flank (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- E2F8 | c.*159_*166del | 3'UTR (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- FAM234B | c.*1172A>G | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- FAT1 | c.*334del | 3'UTR (DEL) | VAF 30/119 reads (25%) | catalogued as rs1231723257; called by mutect2, varscan2
- FRMD7 | c.*682T>C | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- GLIPR2 | c.*81T>G | 3'UTR (SNP) | VAF 70/222 reads (32%) | called by muse, mutect2, varscan2
- GNA12 | c.526-29722G>A | Intron (SNP) | VAF 5/18 reads (28%) | catalogued as rs1344351632; called by muse, mutect2, varscan2
- GREM2 | c.*878T>G | 3'UTR (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.*405T>A | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- IGKV2-26 | n.319G>A | RNA (SNP) | VAF 16/17 reads (94%) | called by muse, mutect2, varscan2
- INPPL1 | c.*429G>A | 3'UTR (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- INSC | c.*510T>C | 3'UTR (SNP) | VAF 28/70 reads (40%) | called by muse, varscan2
- INSC | c.*589C>T | 3'UTR (SNP) | VAF 30/62 reads (48%) | catalogued as rs1372308437; called by muse, varscan2
- KCNG3 | c.*1491G>T | 3'UTR (SNP) | VAF 52/132 reads (39%) | called by muse, mutect2, varscan2
- KLF6 | c.-111C>T | 5'UTR (SNP) | VAF 8/175 reads (5%) | called by muse, mutect2
- KLHL36 | c.*1475del | 3'UTR (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel, varscan2
- LEPROT | c.*206_*219del | 3'UTR (DEL) | VAF 14/50 reads (28%) | called by mutect2, varscan2
- MARCHF4 | c.-348C>T | 5'UTR (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- MMP14 | c.*739G>C | 3'UTR (SNP) | VAF 46/138 reads (33%) | called by muse, varscan2
- MMP14 | c.*857G>T | 3'UTR (SNP) | VAF 44/110 reads (40%) | called by muse, varscan2
- MMP14 | c.*1430G>T | 3'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- MRPL2 | c.96+87T>C | Intron (SNP) | VAF 58/128 reads (45%) | called by muse, varscan2
- MYO3A | c.3000-52A>T | Intron (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- NRG4 | c.*239T>G | 3'UTR (SNP) | VAF 76/132 reads (58%) | called by muse, mutect2, varscan2
- P2RY4 | c.*216A>G | 3'UTR (SNP) | VAF 64/117 reads (55%) | called by muse, mutect2, varscan2
- PDIK1L | c.*224G>A | 3'UTR (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- POSTN | c.*583T>A | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- PPP5C | c.634-79A>G | Intron (SNP) | VAF 43/129 reads (33%) | catalogued as rs574561252; called by muse, mutect2, varscan2
- PRLR | c.*1054G>A | 3'UTR (SNP) | VAF 44/88 reads (50%) | catalogued as rs760739391; called by muse, mutect2, varscan2
- SAMD5 | c.*2981G>A | 3'UTR (SNP) | VAF 16/45 reads (36%) | catalogued as rs1012073161; called by muse, mutect2, varscan2
- SHROOM4 | c.*997+765T>A | Intron (SNP) | VAF 59/108 reads (55%) | called by muse, mutect2, varscan2
- SOCS1 | c.*55A>G | 3'UTR (SNP) | VAF 120/237 reads (51%) | called by muse, mutect2, varscan2
- SRGAP2 | chr1:206463736 T>G | 3'Flank (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- TRDMT1 | c.*829C>T | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- TRPM1 | c.*619C>G | 3'UTR (SNP) | VAF 18/336 reads (5%) | catalogued as rs571675033; called by muse, mutect2
- TSPAN15 | c.735+39G>C | Intron (SNP) | VAF 56/102 reads (55%) | called by muse, mutect2, varscan2
- TTC14 | c.*444C>T | 3'UTR (SNP) | VAF 12/18 reads (67%) | catalogued as rs1031044407; called by muse, varscan2
- TUSC1 | c.*1157A>C | 3'UTR (SNP) | VAF 115/183 reads (63%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1265C>T | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- YY1 | c.*3089_*3090del | 3'UTR (DEL) | VAF 10/28 reads (36%) | called by pindel, varscan2
- ZBED2 | c.-186T>C | 5'UTR (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- ZHX3 | c.*5147C>T | 3'UTR (SNP) | VAF 32/58 reads (55%) | catalogued as rs1220657459; called by muse, mutect2
- ZNF740 | c.*292G>A | 3'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- ZNF75D | c.*1254T>C | 3'UTR (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- ZNRF3 | c.*1772G>A | 3'UTR (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
